Somatic mutation profile of cancer-model specimen HCM-CSHL-0181-C25-85B (3D Organoid, passage 9; aliquot HCM-CSHL-0181-C25-85B-01D-A79L-36), derived from the primary tumor of HCMI case HCM-CSHL-0181-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 60.0 years (21,919 days).
Specimen HCM-CSHL-0181-C25-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54ef779f-4b45-494e-9ab2-cf815b75756e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0181-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0181-C25-10A-01D-A79L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e8ea78aa-a731-4fb6-abbd-d5e404930640

The open-access MAF lists 256 somatic variants for this specimen: 195 protein-altering or splice-affecting, 47 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 156, Silent 47, Frame Shift Del 14, Nonsense Mutation 10, Intron 8, Splice Site 7, In Frame Del 4, 3'UTR 3, Frame Shift Ins 2, Nonstop Mutation 2, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 132/286 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PAH | c.520A>G p.I174V | Missense Mutation (SNP) | VAF 103/237 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.855); catalogued as rs199475632, CM990994; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- PALB2 | c.2509G>T p.E837* | Nonsense Mutation (SNP) | VAF 90/110 reads (82%) | catalogued as rs587778587, CM156713, COSV55163483; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACSM4 | c.1499C>T p.S500L | Missense Mutation (SNP) | VAF 85/385 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.564); catalogued as rs936896432, COSV68068440; called by muse, mutect2, varscan2
- ANOS1 | c.1043G>A p.R348Q | Missense Mutation (SNP) | VAF 50/276 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.231); catalogued as rs143406724, COSV52926229, COSV99390763; called by muse, mutect2, varscan2
- BBS4 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 145/279 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.098); catalogued as rs1251827333; called by muse, mutect2, varscan2
- BEAN1 | c.763C>A p.P255T (on ENST00000536005 / NM_001178020.3; = p.P146T on NM_001136106.5) | Missense Mutation (SNP) | VAF 91/341 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.038); catalogued as rs1323468085; called by muse, mutect2, varscan2
- CD1E | c.259A>C p.K87Q | Missense Mutation (SNP) | VAF 41/379 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1377501869; called by muse, mutect2, varscan2
- CDC25B | c.248G>A p.S83N (on ENST00000245960 / NM_021873.3; = p.S69N on NM_004358.4) | Missense Mutation (SNP) | VAF 215/463 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV55657040; called by muse, mutect2, varscan2
- CFAP46 | c.4271G>C p.W1424S | Missense Mutation (SNP) | VAF 61/444 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63954343; called by muse, mutect2, varscan2
- CRACD | c.2048C>T p.P683L | Missense Mutation (SNP) | VAF 229/371 reads (62%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV99948695; called by muse, mutect2, varscan2
- DAO | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 120/288 reads (42%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.582); catalogued as rs763876748; called by muse, mutect2, varscan2
- DCTD | c.505A>G p.I169V | Missense Mutation (SNP) | VAF 91/241 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as rs1484370761; called by muse, mutect2, varscan2
- DNAH5 | c.9538T>C p.S3180P | Missense Mutation (SNP) | VAF 324/520 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs375817990; called by muse, mutect2, varscan2
- EEPD1 | c.573C>G p.I191M | Missense Mutation (SNP) | VAF 299/488 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV54203600; called by muse, mutect2, varscan2
- FGF9 | c.301G>T p.A101S | Missense Mutation (SNP) | VAF 33/281 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.3); catalogued as COSV101211001; called by muse, mutect2, varscan2
- FPR1 | c.542C>T p.S181L | Missense Mutation (SNP) | VAF 100/373 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.227); catalogued as rs146075164; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPR34 | c.71G>C p.R24P | Missense Mutation (SNP) | VAF 127/426 reads (30%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs142652017, COSV59370464; called by muse, mutect2, varscan2
- GPRIN2 | c.1313G>C p.R438P | Missense Mutation (SNP) | VAF 123/1230 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782444605; called by muse, mutect2
- H1-4 | c.227A>G p.N76S | Missense Mutation (SNP) | VAF 206/349 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs771489271, COSV56801333; called by muse, mutect2, varscan2
- HEPH | c.1268G>A p.R423Q (on ENST00000343002; = p.R156Q on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/222 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs748869673, COSV57958937; called by muse, mutect2, varscan2
- HEY1 | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 145/556 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.05); catalogued as rs1362659627; called by muse, mutect2, varscan2
- HYDIN | c.1184A>G p.D395G | Missense Mutation (SNP) | VAF 174/348 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); catalogued as rs1368857740; called by muse, varscan2
- IPO13 | c.4G>C p.E2Q | Missense Mutation (SNP) | VAF 91/304 reads (30%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.076); catalogued as rs1349299250; called by muse, mutect2, varscan2
- KANK3 | c.1733T>C p.L578P | Missense Mutation (SNP) | VAF 61/385 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs1345330066; called by muse, mutect2, varscan2
- LRRC6 | c.1091C>G p.S364C | Missense Mutation (SNP) | VAF 62/480 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV51542026; called by muse, mutect2, varscan2
- LSM14B | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 87/517 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV99443748; called by muse, mutect2, varscan2
- MASTL | c.1301C>G p.S434C | Missense Mutation (SNP) | VAF 83/267 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.211); catalogued as rs1278184172; called by muse, mutect2, varscan2
- MYH7 | c.5530G>T p.E1844* | Nonsense Mutation (SNP) | VAF 107/459 reads (23%) | catalogued as COSV62519291; called by muse, mutect2, varscan2
- NCAM1 | c.2131G>A p.A711T (on ENST00000316851 / NM_181351.5; = p.A701T on NM_000615.7) | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.966); catalogued as COSV57519322; called by muse, mutect2, varscan2
- NDN | c.856G>C p.D286H | Missense Mutation (SNP) | VAF 93/356 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV59359727; called by muse, mutect2, varscan2
- NLE1 | c.1303G>A p.D435N | Missense Mutation (SNP) | VAF 157/650 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762162494; called by muse, mutect2, varscan2
- NOTCH3 | c.901G>A p.V301M | Missense Mutation (SNP) | VAF 278/527 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775584737, COSV54625419; called by muse, mutect2, varscan2
- NRG2 | c.1987G>T p.G663W | Missense Mutation (SNP) | VAF 75/432 reads (17%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.924); catalogued as rs576149806; called by muse, mutect2, varscan2
- OR10K1 | c.218A>G p.Y73C | Missense Mutation (SNP) | VAF 107/407 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760051434; called by muse, mutect2, varscan2
- OR2T2 | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 101/778 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs558609829, COSV100737782; called by muse, mutect2, varscan2
- PAPPA2 | c.4235T>C p.I1412T | Missense Mutation (SNP) | VAF 21/416 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100868355; called by muse, mutect2
- PCDHGA5 | c.677C>G p.T226R | Missense Mutation (SNP) | VAF 60/366 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.793); catalogued as COSV53982015; called by muse, mutect2, varscan2
- PIK3C2B | c.2434C>T p.R812W | Missense Mutation (SNP) | VAF 422/425 reads (99%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs144230219; called by muse, mutect2, varscan2
- PLA2G4D | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 74/284 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1365178364, COSV51820044; called by muse, mutect2
- PRDM13 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 360/499 reads (72%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs778602675; called by muse, mutect2, varscan2
- RAB11FIP3 | c.829G>A p.G277S | Missense Mutation (SNP) | VAF 50/279 reads (18%) | SIFT tolerated (0.89); PolyPhen possibly damaging (0.862); catalogued as rs201487714, COSV99239731; called by muse, mutect2, varscan2
- RBP1 | c.393C>G p.F131L (on ENST00000619087 / NM_001365940.2; = p.F193L on NM_002899.5) | Missense Mutation (SNP) | VAF 219/600 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51678591; called by muse, mutect2, varscan2
- SLC13A1 | c.1090C>T p.R364* | Nonsense Mutation (SNP) | VAF 135/209 reads (65%) | catalogued as rs752434859, COSV52015614; called by muse, mutect2, varscan2
- SLC6A6 | c.1168C>G p.L390V | Missense Mutation (SNP) | VAF 18/428 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); catalogued as COSV62651242; called by muse, mutect2
- SPHKAP | c.1406C>T p.S469F | Missense Mutation (SNP) | VAF 351/534 reads (66%) | SIFT deleterious (0.05); PolyPhen benign (0.24); catalogued as rs1266466012, COSV100764279, COSV60879334; called by muse, mutect2, varscan2
- SRRT | c.50G>A p.R17K | Missense Mutation (SNP) | VAF 62/216 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as COSV52342204; called by muse, mutect2, varscan2
- TNXB | c.6344C>T p.T2115M (on ENST00000647633; = p.T1868M on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 136/251 reads (54%) | SIFT tolerated (0.18); PolyPhen benign (0.046); catalogued as rs1188559992, COSV64472694; called by muse, mutect2, varscan2
- TPP1 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 91/326 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.039); catalogued as COSV54998188; called by muse, mutect2, varscan2
- TTN | c.13400C>T p.T4467I (on ENST00000591111; = p.T4421I on NM_003319.4) | Missense Mutation (SNP) | VAF 122/340 reads (36%) | PolyPhen possibly damaging (0.711); catalogued as rs376517129; called by muse, mutect2, varscan2
- UCHL1 | c.577C>G p.L193V | Missense Mutation (SNP) | VAF 27/271 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV52650847; called by muse, mutect2, varscan2
- UNC45A | c.2210T>C p.L737P | Missense Mutation (SNP) | VAF 120/648 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67793444; called by muse, mutect2, varscan2
- YTHDC1 | c.1573C>T p.R525C (on ENST00000344157 / NM_001031732.4; = p.R507C on NM_133370.4) | Missense Mutation (SNP) | VAF 188/290 reads (65%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as COSV100704573, COSV100704906; called by muse, mutect2, varscan2
- ZIC2 | c.661A>G p.M221V | Missense Mutation (SNP) | VAF 216/736 reads (29%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.877); catalogued as rs777628868; called by muse, varscan2
- ZSCAN18 | c.141C>G p.F47L | Missense Mutation (SNP) | VAF 147/533 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.399); catalogued as COSV53731238; called by muse, mutect2, varscan2
- A2ML1 | c.2763A>C p.K921N | Missense Mutation (SNP) | VAF 149/301 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- ADGRG4 | c.2560A>G p.T854A | Missense Mutation (SNP) | VAF 124/362 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- ADGRV1 | c.1847C>G p.T616S | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT tolerated (0.64); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- AHNAK2 | c.6951G>T p.K2317N | Missense Mutation (SNP) | VAF 249/249 reads (100%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- ARID5B | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 173/394 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ATP12A | c.1274T>A p.V425D | Missense Mutation (SNP) | VAF 93/194 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ATP23 | c.233G>T p.C78F | Missense Mutation (SNP) | VAF 134/324 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BAG6 | c.3028-11_3036del p.X1010_splice (on ENST00000676571; = p.X963_splice on NM_080702.3 and 1 other RefSeq transcript) | Splice Site (DEL) | VAF 100/407 reads (25%) | called by mutect2, pindel, varscan2
- BICD1 | c.2380_2386del p.L794Tfs*2 | Frame Shift Del (DEL) | VAF 72/451 reads (16%) | called by mutect2, pindel, varscan2
- BRSK2 | c.2032dup p.S678Ffs*26 | Frame Shift Ins (INS) | VAF 119/374 reads (32%) | called by mutect2, pindel, varscan2
- BSN | c.5091_5118del p.L1698Sfs*26 | Frame Shift Del (DEL) | VAF 31/305 reads (10%) | called by mutect2, pindel
- C1orf146 | c.341G>C p.C114S | Missense Mutation (SNP) | VAF 48/183 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- C7 | c.1082A>C p.K361T | Missense Mutation (SNP) | VAF 225/348 reads (65%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- CACNA1S | c.1404C>A p.N468K | Missense Mutation (SNP) | VAF 191/192 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- CAVIN2 | c.985G>C p.E329Q | Missense Mutation (SNP) | VAF 59/511 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- CCDC144A | c.4084A>T p.S1362C | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.073); called by muse, mutect2
- CDH17 | c.1019G>A p.C340Y | Missense Mutation (SNP) | VAF 44/255 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDK12 | c.4334_4356del p.P1445Lfs*60 (on ENST00000447079 / NM_016507.4; = p.P1436Lfs*60 on NM_015083.3) | Frame Shift Del (DEL) | VAF 97/477 reads (20%) | called by mutect2, pindel, varscan2
- CFAP70 | c.576C>A p.Y192* | Nonsense Mutation (SNP) | VAF 62/209 reads (30%) | called by muse, mutect2, varscan2
- CHST8 | c.309_319del p.R104Pfs*166 | Frame Shift Del (DEL) | VAF 260/583 reads (45%) | called by mutect2, pindel, varscan2
- CHST8 | c.439_484del p.V147Rfs*184 | Frame Shift Del (DEL) | VAF 187/605 reads (31%) | called by mutect2, pindel, varscan2
- CIDEC | c.158G>A p.S53N | Missense Mutation (SNP) | VAF 259/529 reads (49%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- CPNE2 | c.1087T>C p.F363L | Missense Mutation (SNP) | VAF 33/299 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DDX3X | c.522_540+13del p.X174_splice (on ENST00000399959; = p.X175_splice on NM_001356.5) | Splice Site (DEL) | VAF 81/178 reads (46%) | called by mutect2, pindel, varscan2
- DHX33 | c.52G>C p.G18R | Missense Mutation (SNP) | VAF 179/376 reads (48%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DIP2B | c.3950G>A p.G1317E | Missense Mutation (SNP) | VAF 163/362 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DKK2 | c.228C>A p.Y76* | Nonsense Mutation (SNP) | VAF 123/194 reads (63%) | called by muse, mutect2, varscan2
- DLGAP2 | c.2676G>T p.E892D | Missense Mutation (SNP) | VAF 47/243 reads (19%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DNMT3A | c.2698C>G p.H900D | Missense Mutation (SNP) | VAF 49/354 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- DYNC2I2 | c.728T>G p.L243W | Missense Mutation (SNP) | VAF 91/442 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- EGFR | c.1073A>C p.H358P | Missense Mutation (SNP) | VAF 161/275 reads (59%) | SIFT tolerated (0.17); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- EGFR | c.1609_1616del p.D537Qfs*6 | Frame Shift Del (DEL) | VAF 91/376 reads (24%) | called by mutect2, pindel, varscan2
- EHD2 | c.1549C>G p.L517V | Missense Mutation (SNP) | VAF 143/554 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- FAM217A | c.303-44_303-1del p.X101_splice | Splice Site (DEL) | VAF 22/128 reads (17%) | called by mutect2, pindel
- FBXO10 | c.1434G>T p.R478S | Missense Mutation (SNP) | VAF 22/192 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- FOSL2 | c.102+1_102+7del p.X34_splice | Splice Site (DEL) | VAF 358/429 reads (83%) | called by mutect2, pindel, varscan2
- FREM2 | c.6868G>C p.V2290L | Missense Mutation (SNP) | VAF 29/433 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2
- GCDH | c.549C>G p.N183K | Missense Mutation (SNP) | VAF 78/448 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- GK5 | c.1120G>C p.V374L | Missense Mutation (SNP) | VAF 111/330 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- GLB1L | c.595_619del p.R199Hfs*3 | Frame Shift Del (DEL) | VAF 62/478 reads (13%) | called by mutect2, pindel
- HSD17B3 | c.469A>T p.N157Y | Missense Mutation (SNP) | VAF 99/320 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HSPA14 | c.1161_1178del p.D388_E393del | In Frame Del (DEL) | VAF 71/190 reads (37%) | called by mutect2, pindel, varscan2
- HSPB8 | c.476C>A p.S159Y | Missense Mutation (SNP) | VAF 134/340 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by mutect2, varscan2
- HTR2B | c.93G>C p.W31C | Missense Mutation (SNP) | VAF 88/372 reads (24%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- IKBKG | c.888G>C p.E296D | Missense Mutation (SNP) | VAF 73/218 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- IL1RAP | c.1547G>C p.R516T | Missense Mutation (SNP) | VAF 82/944 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.574); called by muse, mutect2
- INKA1 | c.61C>T p.R21W | Missense Mutation (SNP) | VAF 174/175 reads (99%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- INPP4B | c.1543G>C p.D515H | Missense Mutation (SNP) | VAF 57/156 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- JAKMIP3 | c.1952T>C p.I651T | Missense Mutation (SNP) | VAF 26/484 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.366); called by muse, mutect2
- KLF10 | c.1080G>T p.Q360H | Missense Mutation (SNP) | VAF 13/357 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.038); called by muse, mutect2
- KMT2C | c.5828C>T p.A1943V | Missense Mutation (SNP) | VAF 37/204 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- LAMA1 | c.452A>G p.Y151C | Missense Mutation (SNP) | VAF 105/473 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- LCE2C | c.229A>T p.R77W | Missense Mutation (SNP) | VAF 72/730 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LHX1 | c.481G>A p.V161M | Missense Mutation (SNP) | VAF 197/863 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LIN9 | c.1316C>G p.T439R (on ENST00000366808 / NM_001270410.2; = p.T384R on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/202 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2
- LRP3 | c.1807C>G p.R603G | Missense Mutation (SNP) | VAF 371/758 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- LRRC15 | c.679_705del p.A227_L235del | In Frame Del (DEL) | VAF 60/578 reads (10%) | called by mutect2, pindel
- LRRIQ1 | c.1073_1078del p.K358_R359del | In Frame Del (DEL) | VAF 38/214 reads (18%) | called by pindel, varscan2
- LRRK1 | c.4214T>A p.I1405N | Missense Mutation (SNP) | VAF 121/414 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, varscan2
- LRRK1 | c.4227_4234del p.Y1410Ffs*7 | Frame Shift Del (DEL) | VAF 94/384 reads (24%) | called by pindel, varscan2
- LSS | c.1852T>C p.F618L | Missense Mutation (SNP) | VAF 223/348 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- LY6K | c.175A>G p.R59G | Missense Mutation (SNP) | VAF 133/533 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- MACC1 | c.1979A>C p.K660T | Missense Mutation (SNP) | VAF 38/280 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- MAGEA8 | c.942G>C p.E314D | Missense Mutation (SNP) | VAF 130/377 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MAN2B1 | c.437-11_444del p.X146_splice | Splice Site (DEL) | VAF 30/346 reads (9%) | called by mutect2, pindel
- MED21 | c.39T>A p.N13K | Missense Mutation (SNP) | VAF 87/338 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- MED23 | c.1122G>T p.W374C | Missense Mutation (SNP) | VAF 39/251 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MNAT1 | c.805C>G p.L269V | Missense Mutation (SNP) | VAF 115/239 reads (48%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- MROH2A | c.4396G>A p.G1466R | Missense Mutation (SNP) | VAF 171/548 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MRPS12 | c.417A>G p.*139Wext*14 | Nonstop Mutation (SNP) | VAF 28/205 reads (14%) | called by muse, mutect2, varscan2
- MUC22 | c.2318C>G p.S773C | Missense Mutation (SNP) | VAF 19/621 reads (3%) | SIFT deleterious (0.02); called by muse, mutect2
- MXRA5 | c.3981G>C p.K1327N | Missense Mutation (SNP) | VAF 110/404 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- MYH15 | c.4517G>A p.G1506D | Missense Mutation (SNP) | VAF 67/296 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- N4BP2 | c.5095G>C p.D1699H | Missense Mutation (SNP) | VAF 71/152 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- NPR1 | c.2570T>C p.V857A | Missense Mutation (SNP) | VAF 41/247 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NSD1 | c.7987_8012del p.W2663Qfs*11 | Frame Shift Del (DEL) | VAF 86/308 reads (28%) | called by mutect2, pindel, varscan2
- NTN3 | c.1362C>G p.I454M | Missense Mutation (SNP) | VAF 105/242 reads (43%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NUP214 | c.1283_1289del p.P428Hfs*60 | Frame Shift Del (DEL) | VAF 49/228 reads (21%) | called by mutect2, pindel, varscan2
- NXPE4 | c.349C>A p.L117M | Missense Mutation (SNP) | VAF 105/213 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR2T11 | c.674T>C p.M225T | Missense Mutation (SNP) | VAF 118/442 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- OR5P3 | c.122_155del p.G41Vfs*18 | Frame Shift Del (DEL) | VAF 34/402 reads (8%) | called by mutect2, pindel
- OR6K6 | c.88G>C p.A30P (on ENST00000368144; = p.A6P on NM_001005184.1) | Missense Mutation (SNP) | VAF 54/367 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- OR8H2 | c.391C>T p.H131Y | Missense Mutation (SNP) | VAF 37/345 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PALB2 | c.2797T>C p.C933R | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PALMD | c.647C>A p.S216* | Nonsense Mutation (SNP) | VAF 10/280 reads (4%) | called by muse, mutect2
- PCDHB14 | c.1619C>G p.A540G | Missense Mutation (SNP) | VAF 25/664 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.597); called by muse, mutect2
- PDK3 | c.1052G>A p.G351D | Missense Mutation (SNP) | VAF 84/294 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PES1 | c.727A>G p.N243D | Missense Mutation (SNP) | VAF 147/331 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- PGAP3 | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 98/374 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- PHF12 | c.233T>G p.F78C | Missense Mutation (SNP) | VAF 112/430 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PKHD1L1 | c.9437A>G p.N3146S | Missense Mutation (SNP) | VAF 50/247 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- PLP1 | c.821G>A p.G274D | Missense Mutation (SNP) | VAF 106/363 reads (29%) | SIFT tolerated (0.9); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- PPEF2 | c.2054G>A p.S685N | Missense Mutation (SNP) | VAF 169/248 reads (68%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- PPP1R12A | c.300_303del p.Q101Lfs*24 | Frame Shift Del (DEL) | VAF 150/349 reads (43%) | called by mutect2, pindel, varscan2
- RABEPK | c.740C>T p.S247L | Missense Mutation (SNP) | VAF 45/304 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- RDH10 | c.946G>A p.G316R | Missense Mutation (SNP) | VAF 181/269 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- RESF1 | c.4768A>C p.T1590P | Missense Mutation (SNP) | VAF 20/370 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RETSAT | c.1210C>T p.P404S | Missense Mutation (SNP) | VAF 55/408 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- RNF2 | c.881A>T p.Y294F | Missense Mutation (SNP) | VAF 26/304 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.383); called by muse, mutect2
- RNF39 | c.1256A>G p.E419G | Missense Mutation (SNP) | VAF 198/344 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- RNF41 | c.940_*15del | Nonstop Mutation (DEL) | VAF 42/252 reads (17%) | called by mutect2, pindel, varscan2
- RSPH4A | c.1207G>T p.E403* | Nonsense Mutation (SNP) | VAF 60/252 reads (24%) | called by muse, mutect2, varscan2
- SENP6 | c.2076-8_2076-1del p.X692_splice | Splice Site (DEL) | VAF 30/149 reads (20%) | called by mutect2, pindel*, varscan2*
- SLC30A2 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 141/142 reads (99%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- SLC7A6 | c.1004C>G p.S335C | Missense Mutation (SNP) | VAF 72/321 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SMCO2 | c.68A>T p.Q23L | Missense Mutation (SNP) | VAF 200/429 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.327); called by muse, mutect2
- SMPD1 | c.122T>A p.L41Q | Missense Mutation (SNP) | VAF 176/572 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.622); called by mutect2, varscan2
- SOX3 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 176/567 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SP8 | c.884C>A p.A295D (on ENST00000361443 / NM_198956.4; = p.A313D on NM_182700.6) | Missense Mutation (SNP) | VAF 172/633 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SPAM1 | c.373G>T p.D125Y | Missense Mutation (SNP) | VAF 123/181 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- SPG7 | c.325A>T p.K109* | Nonsense Mutation (SNP) | VAF 145/235 reads (62%) | called by muse, mutect2, varscan2
- SRGAP3 | c.2841C>A p.S947R | Missense Mutation (SNP) | VAF 48/489 reads (10%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.944); called by muse, mutect2
- ST6GALNAC5 | c.595C>A p.L199M | Missense Mutation (SNP) | VAF 76/244 reads (31%) | PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- SYNE1 | c.16975G>T p.E5659* (on ENST00000367255 / NM_182961.4; = p.E5588* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 32/187 reads (17%) | called by muse, mutect2, varscan2
- SYNM | c.1928T>A p.V643D | Missense Mutation (SNP) | VAF 168/718 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TASOR2 | c.1359G>C p.K453N | Missense Mutation (SNP) | VAF 71/312 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- TGFBR2 | c.971T>C p.I324T | Missense Mutation (SNP) | VAF 139/285 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TOX | c.875C>G p.S292C | Missense Mutation (SNP) | VAF 73/390 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRAF6 | c.1223C>T p.S408F | Missense Mutation (SNP) | VAF 35/262 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRAK1 | c.1537_1541del p.R513Vfs*3 (on ENST00000327628 / NM_001349247.2; = p.R455Vfs*3 on NM_014965.5) | Frame Shift Del (DEL) | VAF 98/249 reads (39%) | called by mutect2, pindel, varscan2
- TRIM64C | c.409dup p.V137Gfs*27 | Frame Shift Ins (INS) | VAF 73/189 reads (39%) | called by mutect2, pindel, varscan2
- TRPM1 | c.1691C>T p.P564L | Missense Mutation (SNP) | VAF 84/321 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TSPAN18 | c.736_744del p.G246_Q248del | In Frame Del (DEL) | VAF 84/355 reads (24%) | called by mutect2, pindel, varscan2
- UPK3A | c.719C>G p.S240C | Missense Mutation (SNP) | VAF 87/205 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- UQCRFS1 | c.77T>C p.L26P | Missense Mutation (SNP) | VAF 192/426 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- USP24 | c.3732-15_3732-1del p.X1244_splice | Splice Site (DEL) | VAF 19/88 reads (22%) | called by mutect2, pindel, varscan2
- USP32 | c.3103C>T p.P1035S | Missense Mutation (SNP) | VAF 195/405 reads (48%) | SIFT tolerated (0.74); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- VARS1 | c.3757G>C p.V1253L | Missense Mutation (SNP) | VAF 67/435 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- VPS13A | c.1804G>C p.V602L | Missense Mutation (SNP) | VAF 83/236 reads (35%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- VSIG10L2 | c.1991T>A p.L664Q | Missense Mutation (SNP) | VAF 175/504 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WAPL | c.1595G>C p.G532A | Missense Mutation (SNP) | VAF 81/227 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- WDR49 | c.257T>A p.L86* (on ENST00000308378 / NM_001366158.1; = p.L427* on NM_001348951.2 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 152/375 reads (41%) | called by muse, mutect2, varscan2
- XRCC5 | c.314C>G p.A105G | Missense Mutation (SNP) | VAF 124/262 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ZBED6 | c.745A>T p.I249F | Missense Mutation (SNP) | VAF 205/322 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- ZC3H18 | c.2417A>T p.Q806L | Missense Mutation (SNP) | VAF 64/656 reads (10%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.725); called by muse, mutect2
- ZDHHC8 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 46/318 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- ZNF217 | c.2350T>G p.S784A | Missense Mutation (SNP) | VAF 122/681 reads (18%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF254 | c.706A>C p.K236Q | Missense Mutation (SNP) | VAF 63/294 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- ZNF280B | c.554_555del p.P185Qfs*4 | Frame Shift Del (DEL) | VAF 55/280 reads (20%) | called by mutect2, pindel, varscan2
- ZNF770 | c.108T>A p.F36L | Missense Mutation (SNP) | VAF 80/207 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ACTRT3 | c.480G>A p.Q160= | Silent (SNP) | VAF 39/651 reads (6%) | called by muse, mutect2
- ADGRG4 | c.7680G>C p.T2560= | Silent (SNP) | VAF 150/490 reads (31%) | called by muse, mutect2, varscan2
- BHLHE40 | c.987A>C p.P329= | Silent (SNP) | VAF 40/630 reads (6%) | called by muse, mutect2
- CDC25B | c.249C>T p.S83= (on ENST00000245960 / NM_021873.3; = p.S69= on NM_004358.4) | Silent (SNP) | VAF 216/463 reads (47%) | called by muse, mutect2, varscan2
- CLEC7A | c.555G>A p.R185= (on ENST00000304084 / NM_197947.3; = p.R139= on NM_022570.5) | Silent (SNP) | VAF 76/526 reads (14%) | called by muse, mutect2, varscan2
- COPA | c.3267C>A p.A1089= | Silent (SNP) | VAF 26/354 reads (7%) | called by muse, mutect2
- CSMD1 | c.1206C>T p.D402= (on ENST00000520002; = p.D401= on NM_033225.6) | Silent (SNP) | VAF 33/189 reads (17%) | called by muse, mutect2, varscan2
- CXCR1 | c.339C>G p.V113= | Silent (SNP) | VAF 62/625 reads (10%) | called by muse, mutect2, varscan2
- DLX5 | c.675G>A p.E225= | Silent (SNP) | VAF 189/489 reads (39%) | called by muse, mutect2, varscan2
- DOK5 | c.576G>A p.T192= | Silent (SNP) | VAF 126/334 reads (38%) | catalogued as rs760518434; called by muse, varscan2
- EOMES | c.966G>A p.A322= | Silent (SNP) | VAF 230/230 reads (100%) | catalogued as rs1202281120, COSV55416481; called by muse, mutect2, varscan2
- FBXW10 | c.1710C>T p.L570= | Silent (SNP) | VAF 58/268 reads (22%) | catalogued as rs1464802398; called by muse, varscan2
- FREM2 | c.8043G>A p.V2681= | Silent (SNP) | VAF 86/372 reads (23%) | called by muse, mutect2, varscan2
- FREM3 | c.2880A>G p.L960= | Silent (SNP) | VAF 178/272 reads (65%) | called by muse, mutect2, varscan2
- GALNT9 | c.1236G>T p.V412= (on ENST00000328957 / NM_001122636.2; = p.V46= on NM_021808.3) | Silent (SNP) | VAF 143/289 reads (49%) | called by muse, mutect2, varscan2
- GIMAP2 | c.657C>T p.Y219= | Silent (SNP) | VAF 182/236 reads (77%) | called by muse, varscan2
- ITCH | c.2421A>G p.K807= (on ENST00000262650 / NM_001257137.3; = p.K766= on NM_031483.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 109/251 reads (43%) | called by muse, mutect2, varscan2
- KDM8 | c.261A>G p.V87= | Silent (SNP) | VAF 44/375 reads (12%) | called by muse, varscan2
- KIAA1614 | c.798C>A p.V266= | Silent (SNP) | VAF 61/507 reads (12%) | called by muse, mutect2, varscan2
- KRT84 | c.1464C>T p.S488= | Silent (SNP) | VAF 82/392 reads (21%) | called by muse, mutect2, varscan2
- KYNU | c.261T>C p.L87= | Silent (SNP) | VAF 21/296 reads (7%) | called by muse, mutect2
- MARCHF11 | c.108G>A p.P36= | Silent (SNP) | VAF 183/484 reads (38%) | called by muse, mutect2, varscan2
- PATE2 | c.237G>A p.S79= | Silent (SNP) | VAF 165/247 reads (67%) | catalogued as rs377705832; called by muse, mutect2, varscan2
- PHF8 | c.1833C>T p.N611= (on ENST00000357988 / NM_001184896.1; = p.N575= on NM_015107.3) | Silent (SNP) | VAF 56/221 reads (25%) | catalogued as rs374668419, COSV57678138; ClinVar: likely benign; called by muse, mutect2, varscan2
- PHF8 | c.921A>T p.P307= (on ENST00000357988 / NM_001184896.1; = p.P271= on NM_015107.3) | Silent (SNP) | VAF 74/356 reads (21%) | called by muse, mutect2, varscan2
- PIK3R4 | c.204A>G p.K68= | Silent (SNP) | VAF 32/332 reads (10%) | called by muse, mutect2, varscan2
- PPP1R10 | c.2049G>T p.P683= | Silent (SNP) | VAF 140/504 reads (28%) | catalogued as COSV100919909; called by muse, varscan2
- PRKAG2 | c.369C>T p.F123= | Silent (SNP) | VAF 33/277 reads (12%) | called by muse, mutect2, varscan2
- RBFOX1 | c.384C>T p.F128= | Silent (SNP) | VAF 189/231 reads (82%) | catalogued as rs536057811, COSV60959510; called by muse, mutect2, varscan2
- RFX1 | c.2269C>T p.L757= | Silent (SNP) | VAF 150/620 reads (24%) | called by muse, mutect2, varscan2
- RHCG | c.444C>T p.P148= | Silent (SNP) | VAF 88/598 reads (15%) | called by muse, mutect2, varscan2
- RHOF | c.396G>A p.K132= | Silent (SNP) | VAF 68/711 reads (10%) | catalogued as rs769369334; called by muse, mutect2
- RNF17 | c.4233A>C p.G1411= | Silent (SNP) | VAF 30/314 reads (10%) | called by muse, mutect2
- ROBO2 | c.1728G>A p.K576= | Silent (SNP) | VAF 46/458 reads (10%) | catalogued as COSV59908687; called by muse, mutect2
- SLC16A5 | c.528C>A p.G176= | Silent (SNP) | VAF 105/708 reads (15%) | called by muse, mutect2, varscan2
- SLC49A4 | c.1125A>T p.L375= | Silent (SNP) | VAF 61/257 reads (24%) | called by muse, mutect2, varscan2
- SOX9 | c.834G>C p.L278= | Silent (SNP) | VAF 64/814 reads (8%) | catalogued as COSV55423356, COSV55424109, COSV55428800; called by muse, mutect2
- SPATA31A3 | c.2190G>C p.L730= | Silent (SNP) | VAF 77/612 reads (13%) | called by muse, mutect2, varscan2
- STAG1 | c.3615C>A p.S1205= | Silent (SNP) | VAF 72/415 reads (17%) | called by muse, mutect2, varscan2
- TADA2B | c.666C>T p.I222= | Silent (SNP) | VAF 63/664 reads (9%) | catalogued as rs760620156; called by muse, mutect2
- TMEM104 | c.1194C>T p.V398= | Silent (SNP) | VAF 77/768 reads (10%) | catalogued as rs746234547; called by muse, mutect2, varscan2
- TMPRSS11E | c.1185A>T p.G395= | Silent (SNP) | VAF 62/348 reads (18%) | called by muse, mutect2, varscan2
- TRIM37 | c.2532T>C p.S844= | Silent (SNP) | VAF 73/364 reads (20%) | called by muse, mutect2, varscan2
- TRRAP | c.4503C>A p.P1501= | Silent (SNP) | VAF 30/215 reads (14%) | called by muse, mutect2, varscan2
- UBE2O | c.2661C>T p.R887= | Silent (SNP) | VAF 143/619 reads (23%) | catalogued as rs34371138; called by muse, mutect2, varscan2
- WNK2 | c.2601G>A p.A867= | Silent (SNP) | VAF 150/567 reads (26%) | catalogued as rs375757039; called by muse, mutect2, varscan2
- ZNF385D | c.651G>C p.S217= | Silent (SNP) | VAF 37/142 reads (26%) | catalogued as COSV55752499; called by muse, mutect2, varscan2
- AC244197.3 | c.*2327T>C | 3'UTR (SNP) | VAF 56/206 reads (27%) | called by muse, mutect2, varscan2
- AJAP1 | c.*336G>T | 3'UTR (SNP) | VAF 214/214 reads (100%) | called by muse, mutect2, varscan2
- FOXO3B | chr17:18663166 C>T | 3'Flank (SNP) | VAF 130/404 reads (32%) | catalogued as rs1205989868; called by muse, mutect2
- FRMD1 | chr6:168081458 C>A | 5'Flank (SNP) | VAF 107/361 reads (30%) | called by muse, mutect2, varscan2
- HNRNPLL | c.802+32G>C | Intron (SNP) | VAF 67/312 reads (21%) | called by muse, mutect2, varscan2
- MGAM | c.4619-13710G>C | Intron (SNP) | VAF 32/202 reads (16%) | called by muse, mutect2, varscan2
- NR2F2 | c.-680G>T | 5'UTR (SNP) | VAF 266/1080 reads (25%) | called by muse, varscan2
- PIKFYVE | c.322+314A>C | Intron (SNP) | VAF 51/336 reads (15%) | called by muse, mutect2, varscan2
- PNCK | c.539-44T>G | Intron (SNP) | VAF 163/518 reads (31%) | called by muse, mutect2, varscan2
- RNMT | c.*2118A>G | 3'UTR (SNP) | VAF 32/464 reads (7%) | called by muse, mutect2
- SHLD2 | c.1964-4081_1964-4037del | Intron (DEL) | VAF 35/198 reads (18%) | called by mutect2, pindel, varscan2
- STXBP1 | c.1702+1865T>G | Intron (SNP) | VAF 44/530 reads (8%) | called by muse, mutect2
- TRIM9 | c.2070+85G>A | Intron (SNP) | VAF 172/366 reads (47%) | catalogued as rs771685381; called by muse, mutect2, varscan2
- UNC5A | c.721+666G>A | Intron (SNP) | VAF 116/349 reads (33%) | catalogued as rs559693536; called by muse, mutect2, varscan2
